Surgical pathology report (de-identified scan), TCGA case TCGA-KK-A8IL, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-KK-A8IL-01A (Primary Tumor).

[page 1 of 3]
Specimen Date/Time:

***** MODIFIED REPORT - REVIEW ADDENDUM SECTION *****

DIAGNOSIS

(A) PROSTATE AND SEMINAL VESICLES:

Supplemental report to follow.

(B) RIGHT PELVIC LYMPH NODES:

Four lymph nodes, no tumor present.(0/4)

(C) LEFT PELVIC LYMPH NODES:

METASTATIC ADENOCARCINOMA IN ONE OUT OF FOUR LYMPH NODES (1/4), CONSISTENT WITH A
PROSTATIC PRIMARY.

SIZE OF METASTASIS: 0.3 CM.

ASCE ICD-O-3
Adenocarcinoma, acinar 8140/3
path Adenocarcinoma NOS 8140/3
Site: Prostate NOS C61.9
gn 11/24/13

GROSS DESCRIPTION

(A) PROSTATE AND SEMINAL VESICLES - Supplemental report to follow.

(B) RIGHT PELVIC LYMPH NODE - Received is a portion of fibroadipose tissue (9 x 5 x 0.8 cm). Dissection reveals multiple possible lymph nodes, ranging in size from 0.5 to 2.8 cm. All lymph nodes are submitted as follows: B1, B2, largest lymph node, serially sectioned; B3, one lymph node, bisected; B4, two possible lymph nodes, intact.

(C) LEFT PELVIC LYMPH NODE - A portion of fibroadipose tissue (10 x 4 x 1 cm), containing multiple possible lymph nodes ranging in size from 0.3 to 2 cm in greatest dimension. All lymph nodes are submitted as follows: C1, two possible lymph nodes, intact; C2, one lymph node, bisected; C3, one lymph node, bisected.

CLINICAL HISTORY

None given.

SNOMED CODES

"Some tests reported here may have been developed and performance characteristics determined by specifically cleared or approved by the U.S. Food and Drug Administration."
Entire report and diagnosis completed by:

These tests have not been

Start of ADDENDUM

[page 2 of 3]
Accession: [REDACTED]
Specimen Date/Time: [REDACTED]

ADDENDUM

This modified report is being issued to provide additional information/results.

Addendum completed by

DIAGNOSIS

(A) PROSTATE AND SEMINAL VESICLES:

PROSTATIC ADENOCARCINOMA GLEASON SCORE 9 (4+5). (SEE COMMENT)
EXTRAPROSTATIC EXTENSION PRESENT.
TUMOR INVADING RIGHT AND LEFT SEMINAL VESICLES AND PERIVESICULAR SOFT TISSUE.
TUMOR EXTENDING FOCALLY TO THE MARGIN OF RESECTION.
PROSTATIC INTRAEPITHELIAL NEOPLASIA, HIGH-GRADE.
SEE PREVIOUS REPORT FOR DIAGNOSIS OF PELVIC LYMPH NODES.

COMMENT

The prostate gland contains a single focus of prostatic adenocarcinoma. The tumor is located in the left anterolateral, left lateral, left posterolateral, left posterior, mid posterior and right posterior peripheral zone. The tumor focus measures 2.3 x 1.5 cm in the largest cross-sectional dimension and it is present in the four cross sections of the prostate and extensively in the apex and base regions. The tumor exhibits extraprostatic extension in the left posterolateral surface of the prostate and left superior neurovascular bundle region. The extent of extraprostatic extension is 3.5 mm. The tumor extensively invades both right and left seminal vesicles including intra and extraprostatic portions. Extension into perivesicular soft tissue is also present. Tumor extends focally to the margin of resection in the left posterolateral surface and left superior neurovascular bundle region. The extent of marginal involvement is approximately 1.0 mm.

Please refer to the previous report for the diagnosis of the pelvic lymph nodes.

GROSS DESCRIPTION

(A) PROSTATE AND SEMINAL VESICLES - A prostate, attached right and left seminal vesicles and attached segments of right and left vasa deferentia.

The prostate gland (4.2 x 3.7 x 3.3 cm, 29 gm, postfixation) has the usual shape. The soft tissue present along the right and left posterolateral aspects of the prostate appears symmetrical. A nodule is palpated on the left side of the prostate. Serial cross sections after demonstrate a firm area of possible tumor in the left posterolateral peripheral zone of the first two of the four cross sections of the prostate.

The seminal vesicles and segments of vasa deferentia are grossly free of tumor.

SECTION CODE: A1, A2, base of right seminal vesicle and right vas deferens; A3, A4, base of left seminal vesicle and left vas deferens; A5, prostatic base right border; A6, A7, prostatic base right posterior border; A8-A11, prostatic base central portion; A12, prostatic base left border; A13, A14, prostatic base left posterior border; A15, apex anterior; A16, A17, apex left; A18,

[page 3 of 3]
Accession: [REDACTED]
Specimen Date/Time:

A19, apex posterior; A20, A21, apex right; A22, detached portions of margin of resection according to specimen radiograph; A23-A38, sections of the four cross sections of the prostate according to specimen radiograph.

The anterior aspect of the prostate is inked in green, left surface in red, right surface in yellow and posterior surface in black. Orange ink (A29, 30, 33, 34 and 38) denotes surfaces that do not represent the true margin of resection.

SNOMED CODES

Entire report and diagnosis completed by:

-----END OF REPORT-----

Source: NCI Genomic Data Commons file d9a8c674-5465-464f-a041-89adb01ad613 (TCGA-KK-A8IL.9F54DC02-35C0-4D0E-A1D8-63F820CF72C4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).